Gene-level copy-number profile of tumor specimen TCGA-F1-6875-01A from TCGA case TCGA-F1-6875, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 80.0 years (29,209 days).
Specimen TCGA-F1-6875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.86311315-fd39-4bd3-a156-fad566eccea5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F1-6875-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5eedf78f-305d-4daa-b6f0-72065071d0ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 195; copy number 1: 3,973; copy number 2: 29,333; copy number 3: 19,397; copy number 4: 4,652; copy number 5: 1,556; copy number 6: 539; copy number 7: 54; copy number 8: 111; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F1-6875-01A-11D-2052-01): tumor purity 0.89, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr9:14,475–492,248, 12 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1.
- chr9:477,750–495,610, 2 genes: RPL12P25, AL161725.2.
- chr9:1,328,664–2,193,624, 5 genes (within-gene range 0–7): AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2.
- chr9:2,162,763–2,229,241, 2 genes: RNU2-25P, RN7SL592P.
- chr9:3,218,297–3,691,814, 5 genes (within-gene range 0–5): RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:8,314,246–10,612,723, 6 genes (within-gene range 0–8): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1.
- chr9:9,442,060–9,803,784, 2 genes: RN7SL5P, AL513422.1.
- chr9:10,829,752–13,034,326, 18 genes: IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1.
- chr9:13,322,806–13,987,909, 6 genes: AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2.
- chr9:14,317,073–15,307,360, 18 genes: AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:16,726,814–17,797,124, 11 genes (within-gene range 0–7): BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:20,999,509–23,672,387, 62 genes (within-gene range 0–9) (broad region; genes not listed).
- chr9:26,066,675–27,944,497, 27 genes: AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr11:22,813,799–22,945,393, 3 genes: SVIP, AC006299.1, CCDC179.
- chr11:24,235,477–25,141,023, 5 genes: LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.
- chr16:78,981,722–79,017,429, 3 genes: AC027279.3, AC027279.2, AC009145.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,265 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,011,687–114,670,422, 33 genes, copy number 5 (within-gene range 3–5): LRIG2-DT, LRIG2, RLIMP2, AL357055.1, AL357055.2, MAGI3, AL391058.1, MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1, OLFML3, AL591742.1, AL591742.2, SYT6, AL121999.1, MRPL57P1, AL035410.2, TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C.
- chr9:470,291–746,106, 1 gene, copy number 7 (within-gene range 0–7): KANK1.
- chr9:547,135–1,164,867, 13 genes, copy number 7: AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14.
- chr9:2,041,900–2,046,023, 1 gene, copy number 7: AL359076.1.
- chr9:2,621,787–3,200,445, 8 genes, copy number 5–8: VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231.
- chr9:3,824,127–7,961,224, 88 genes, copy number 8 (within-gene range 0–8) (broad region; genes not listed).
- chr9:10,532,145–10,777,525, 4 genes, copy number 8: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1.
- chr9:13,105,706–13,279,692, 2 genes, copy number 7: MPDZ, AL162386.2.
- chr9:17,906,563–20,995,955, 38 genes, copy number 6–7 (within-gene range 0–7): ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD.
- chr9:20,716,105–20,787,055, 2 genes, copy number 6: MIR491, SNORA30B.
- chr9:23,632,106–25,938,434, 17 genes, copy number 5: SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr9:29,636,486–29,826,711, 2 genes, copy number 10: AL354676.1, ME2P1.
- chr9:31,165,618–34,048,949, 76 genes, copy number 5–10 (broad region; genes not listed).
- chr9:34,252,381–34,524,241, 12 genes, copy number 8 (within-gene range 1–8): KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1.
- chr15:46,317,393–101,933,350, 1,363 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–26,251,546, 540 genes, copy number 5–6 (broad region; genes not listed).
- chr20:52,192,159–56,786,087, 65 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
